Somatic mutation profile of tumor specimen TCGA-H9-A6BX-01A (aliquot TCGA-H9-A6BX-01A-31D-A30X-08) from TCGA case TCGA-H9-A6BX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.3 years (22,039 days).
Specimen TCGA-H9-A6BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac23376a-5438-47a8-8312-f2425da8f237.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H9-A6BX-10A (Blood Derived Normal), aliquot TCGA-H9-A6BX-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c83c423f-0975-4b6e-8edd-1d1a5ddebc2a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJB8 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV59879229; called by muse, mutect2
- RYR1 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444347791, COSV100616897, COSV62104914; ClinVar: uncertain significance; called by muse, mutect2
- SETD2 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 12/259 reads (5%) | catalogued as rs976581260, COSV57434358; called by muse, mutect2
- KIF1B | c.2133G>A p.L711= (on ENST00000377086 / NM_001365952.1; = p.L665= on NM_015074.3) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV55812854; called by muse, mutect2, varscan2
